Gene-level copy-number profile of tumor specimen ALCH-ADSW-TTP1-A from ALCHEMIST case ALCH-ADSW, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma in situ, NOS; Age at diagnosis: 62.5 years (22,828 days).
Specimen ALCH-ADSW-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e83e41a1-3aa6-4ace-9325-f0a983057249.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ADSW-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,236 have no estimate.
https://portal.gdc.cancer.gov/files/51fa690d-316e-4757-bb3d-780a28058d2b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 58; copy number 1: 7,138; copy number 2: 48,892; copy number 3: 2,190; copy number 4: 84; copy number 5: 25.

Homozygous deletions (total copy number 0; autosomes only): 28 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:73,209,083–73,210,080, 1 gene (within-gene range 0–1): KHDC1P1.
- chr6:107,028,199–107,133,170, 3 genes: MTRES1, BEND3, RNU6-1299P.
- chr6:107,192,300–107,192,573, 1 gene (within-gene range 0–1): AL591516.1.
- chr7:102,464,956–102,473,168, 3 genes (within-gene range 0–2): LRWD1, MIR5090, MIR4467.
- chr8:33,591,330–33,600,023, 1 gene: DUSP26.
- chr8:33,641,581–33,641,939, 1 gene (within-gene range 0–1): BUD31P1.
- chr12:57,128,483–57,251,188, 8 genes (within-gene range 0–2): LRP1, LRP1-AS, MIR1228, NXPH4, AC137834.2, SHMT2, NDUFA4L2, STAC3.
- chr13:113,399,610–113,453,524, 1 gene (within-gene range 0–1): ADPRHL1.
- chr17:142,789–191,587, 2 genes (within-gene range 0–1): DOC2B, LINC02091.
- chr17:22,266,395–22,332,410, 4 genes: AC138761.1, AC138761.2, FAM27E5, AC087575.1.
- chr17:47,694,081–47,712,050, 1 gene: TBKBP1.
- chr19:16,065,737–16,066,312, 1 gene: LINC01855.
- chr20:31,637,912–31,645,006, 1 gene: COX4I2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 25 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:242,087,351–242,175,634, 5 genes, copy number 5: AC093642.2, LINC01881, CICP10, SEPTIN14P2, RPL23AP88.
- chr5:135,802,985–135,803,075, 1 gene, copy number 5: MIR5692C1.
- chr20:62,642,503–62,685,785, 4 genes, copy number 5 (within-gene range 2–5): SLCO4A1, AL357033.4, AL357033.3, SLCO4A1-AS1.
- chr20:62,774,121–63,007,035, 13 genes, copy number 5: LINC00659, MRGBP, OGFR-AS1, OGFR, COL9A3, TCFL5, DPH3P1, ARF4P2, DIDO1, AL117379.1, GID8, SLC17A9, BHLHE23.
- chr21:45,073,853–45,226,560, 2 genes, copy number 5 (within-gene range 2–5): ADARB1, AL133499.1.

Autosomal genes at a single copy (total copy number 1): 7,027. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
